Somatic mutation profile of tumor specimen 0DSA09 from CCDI case PBCHXM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ganglioglioma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.2 years (3,371 days).
Specimen 0DSA09: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9bab24db-70a7-4e09-ae7b-10700c855196.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSA1H (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1624ff86-77f6-4b6e-8a5f-c62d87960496

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Nonsense Mutation 2, Missense Mutation 2, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APOBEC3B | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 135/450 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs766117548, COSV59841046; called by muse, mutect2, varscan2
- CREBBP | c.4672C>T p.Q1558* | Nonsense Mutation (SNP) | VAF 185/570 reads (32%) | catalogued as CM030211; called by muse, mutect2, varscan2
- SAMD13 | c.181C>T p.R61* (on ENST00000370671; = p.R55* on NM_001010971.3) | Nonsense Mutation (SNP) | VAF 183/549 reads (33%) | catalogued as rs749289486; called by muse, mutect2, varscan2
- BRAF | c.1630_1637+1dup p.X544_splice (on ENST00000288602 / NM_001374244.1; = p.X504_splice on NM_004333.6 and 3 other RefSeq transcripts) | Splice Site (INS) | VAF 76/330 reads (23%) | called by mutect2, varscan2
- FRAS1 | c.1334T>C p.L445P | Missense Mutation (SNP) | VAF 156/484 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARPC2 | c.455+56C>G | Intron (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
